Surgical pathology report (de-identified scan), TCGA case TCGA-AZ-4315, project TCGA-COAD (Colon Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-AZ-4315-01A (Primary Tumor).

FINAL DIAGNOSIS:

TERMINAL ILEUM AND RIGHT COLON, RIGHT HEMI-COLECTOMY -

- A. INVASIVE MODERATELY DIFFERENTIATED ADENOCARCINOMA (5.5 CM) OF CECUM.
- B. ADENOCARCINOMA INVADES THROUGH MUSCULARIS PROPRIA TO SUBSEROUS ADIPOSE TISSUE.
- C. PROXIMAL, DISTAL, AND RADIAL MARGINS FREE OF CARCINOMA.
- D. NO ANGIOLYMPHATIC INVASION PRESENT.
- E. NO PERINEURAL INVASION PRESENT.
- F. TWENTY-FIVE BENIGN PERICOLONIC LYMPH NODES (0/25).
- G. PATHOLOGIC TUMOR STAGE pT3a, N0, MX.
- H. TERMINAL ILEUM WITH NO SIGNIFICANT ABNORMALITY.
- I. APPENDIX WITH NO SIGNIFICANT ABNORMALITY.

TCGA-AZ-4315

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY COLON, RECTAL, APPENDIX TUMORS

SPECIMEN TYPE:	Right hemicolectomy
SPECIMEN LENGTH:	24 cm
TUMOR SITE:	Cecum
TUMOR CONFIGURATION:	Exophytic (polypoid)
TUMOR SIZE:	Greatest dimension: 5.5 cm Additional dimensions: 4.0 X 1.3 cm
INTACTNESS OF MESORECTUM:	Not applicable
HISTOLOGIC TYPE:	Adenocarcinoma
HISTOLOGIC GRADE:	Low-grade (well to moderately differentiated)
PATHOLOGIC STAGING (pTNM):	pT3a/b pN0 Number of nodes examined: 25 Number of nodes involved: 0 pMX
MARGINS:	Proximal margin uninvolved by invasive carcinoma Distal margin uninvolved by invasive carcinoma Circumferential (radial) margin - Not applicable Mesenteric margin uninvolved by invasive carcinoma
ANGIOLYMPHATIC INVASION:	Absent
PERINEURAL INVASION:	Absent
TUMOR BORDER CONFIGURATION:	Infiltrating
TUMORAL LYMPHOCYTIC RESPONSE:	Mild to moderate

Source: NCI Genomic Data Commons file e8bde9ed-7bae-48bd-8dab-0ec3d990bd28 (TCGA-AZ-4315.927B4861-C24E-4CE4-B7DD-2C950F2FB947.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).